Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8296, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8296-01A (Primary Tumor).

[page 1 of 6]
	Description

--

--

[page 2 of 6]
Microscopic Description	Diagnosis Details

[page 3 of 6]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 9.5 x 8 x 1.2 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma, intestinal type Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - lesser omentum Lymph nodes: 6/7 positive for metastasis (Intraabdominal 6/7) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 4 of 6]
Laterality		ID

[page 5 of 6]
Excision date		Case ID	

Source: NCI Genomic Data Commons file 65e87a94-f6f9-49bf-97c1-ec09b9d78fa5 (TCGA-BR-8296.C9F1E9C4-D693-470A-B49C-551BD8FB890B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).